Surgical pathology report (de-identified scan), TCGA case TCGA-MT-A67A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Minnesota, specimen TCGA-MT-A67A-01A (Primary Tumor).

[page 1 of 9]
study subject ID:

ID:

Tumor ID:

Collected:

Received:

SPECIMEN(S):

A: Right superior margin

B: Right anterior margin

C: Right inferior margin

D: Right posterior margin

E: Right deep margin

F: Right glossectomy

G: Re-resection posterior margin

H: Re-resection inferior margin

I: Re-resection inferior margin #2

J: Level 1, right

K: Level 2A, right

L: Level 2B, right

M: Level 3

FINAL DIAGNOSIS:

A. Right superior margin:

- Benign tongue tissue with no evidence of malignancy.

ICD-0-3

Carcinoma, squamous cell NOS
8070/3

Site Tongue NOS C02.9
J25/10/13

[page 2 of 9]
B. Right anterior margin:

- Benign tongue tissue with no evidence of malignancy.

C. Right inferior margin:

- Invasive squamous carcinoma.

D. Right posterior margin:

- Mild dysplasia.
- No evidence of malignancy.

E. Right deep margin:

- Benign tongue tissue with no evidence of malignancy.

F. Right glossectomy:

- Squamous cell carcinoma, invasive, moderately to well differentiated.
- Tumor size: 1.7 x 1.4 X 1.5 cm.
- Maximum depth of invasion: 1.5 cm.
- Perineural invasion: Absent.
- Vascular invasion: Absent.
- Surgical Margins:
- Microscopic (0.1 cm) tumor present at deep margin.
- (May not represent final deep margin, see specimen

E).

[page 3 of 9]
- Other margins negative as follows:

Posterior: 0.4 cm; inferior: 0.5 cm; anterior and superior: 1.0 cm.

G. Re-resection posterior margin:

- Negative for malignancy.

H. Re-resection inferior margin:

- Moderate dysplasia present.

- No evidence of invasive malignancy.

I. Re-resection inferior margin #2:

- Negative for malignancy.

J. Level 1, right:

- Three benign lymph nodes with no evidence of malignancy (0/3 lymph nodes).

- Benign salivary gland tissue.

K. Level 2A, right:

- Two benign lymph nodes with no evidence of malignancy (0/2 lymph nodes).

- Small fragment of benign thyroid gland tissue.

L. Level 2B, right:

[page 4 of 9]
- Six benign lymph nodes with no evidence of malignancy (0/6 lymph nodes).

M. Level 3:

- Nine benign lymph nodes with no evidence of malignancy (0/9 lymph nodes).

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

-year-old female with squamous cell carcinoma of the right floor of mouth involving the lateral border of tongue.

PROCEDURE: Submental platysmal flap rotation to reconstruct the right lateral border of tongue and floor of mouth.

GROSS:

Thirteen specimens are received, each labeled with the patient's name and hospital number.

[page 5 of 9]
A. Specimen A is designated "right superior margin." The specimen consists of a 6.2 x 0.7 x 0.6 cm unoriented red/tan soft tissue fragment. The specimen is submitted intact for frozen section analysis in one cassette.

B. Specimen B is designated "right anterior margin." The specimen consists of a single pink/tan soft tissue fragment measuring 1.2 x 1.1 x 0.4 cm in greatest dimension. The specimen is submitted intact for frozen section analysis in one cassette.

C. Specimen C is designated "right inferior margin." The specimen consists of a single pink/tan soft tissue fragment measuring 2.1 x 0.8 x 0.5 cm in greatest dimension. The specimen is submitted intact for frozen section analysis in one cassette.

D. Specimen D is designated "right posterior margin." The specimen consists of a 0.7 x 0.6 x 0.4 cm unoriented red/tan soft tissue fragment. The specimen is submitted intact for frozen section analysis in one cassette.

E. Specimen E is designated "right deep margin." The specimen consists of two red/tan soft tissue fragments measuring 0.8 x 1.2 cm in greatest dimension. The specimen is submitted intact for frozen section analysis in one cassette.

[page 6 of 9]
F. Specimen F is designated "right glossectomy." The specimen consists of an oriented right glossectomy measuring 4.7 x 3.3 x 2.5 cm. The specimen is inked as follows: anterior - orange, superior - blue, deep/medial - black, posterior - green, inferior - red. On the lateral surface there is a variegated lesion which is tan/white in color and firm in consistency measuring 1.7 x 1.4 cm with a depth of 1.5 cm. Sectioning reveals a variable pale tan/white color. Grossly the tumor is 0.1 cm from the black medial margin. It measures 1.0 cm from the superior (blue) margin, 0.5 cm from inferior (red), 0.4 cm from posterior (green), and 1.0 cm from anterior (orange) margin. In addition, on the posterior lateral portion of the specimen there is a tan ulcer measuring 1.0 x 0.4 cm. Representative tissue was procured for potential future studies.

G. Specimen G is designated "re-resection posterior margin." The specimen consists of two red/tan soft tissue fragments measuring 1.8 x 3.1 cm in greatest dimension. The specimen is submitted intact for frozen section analysis in one cassette.

H. Specimen H is designated "re-resection inferior margin." The specimen consists of a single pink/tan soft tissue fragment measuring 3.7 x 1.3 x 0.6 cm in greatest dimension. The specimen is submitted intact for frozen section analysis in one cassette.

[page 7 of 9]
I. Specimen I is designated "re-resection inferior margin #2."

The specimen consists of a 2.6 x 2 x 0.8 cm fragment of pink/tan soft tissue. The specimen (95%) is submitted for frozen section analysis in one cassette with the remainder (5%) submitted for permanent sections.

J. Specimen J is designated "level 1, right." The specimen consists of a single irregular unoriented glistening yellow/tan soft tissue fragment measuring 7.5 x 3.4 x 1.2 cm in greatest dimension. The soft tissue is dissected revealing four potential lymph nodes ranging from 0.3 to 0.5 cm in greatest dimension. Also identified is a salivary gland with unremarkable cut surfaces. A representative section of the salivary gland is submitted along with entire lymph nodes. The specimen is submitted in two cassettes.

K. Specimen K is designated "level 2A, right." The specimen consists of a single unoriented partially encapsulated tan/yellow soft tissue fragment measuring 5.5 x 4.8 x 1.8 cm in greatest dimension. The soft tissue is dissected revealing seven potential lymph nodes ranging from 0.2 to 2.2 cm in greatest dimension. The lymph nodes are submitted intact.

L. Specimen L is designated "level 2B, right." The specimen consists of a single irregular tan/yellow soft tissue fragment measuring 3.4 x 1.6 x 1.0 cm in greatest dimension. The soft tissue is dissected

[page 8 of 9]
revealing six potential lymph nodes ranging from 0.3 to 0.4 cm in greatest dimension. The lymph nodes are submitted intact.

M. Specimen M is designated "level 3." The specimen consists of a single unoriented membranous tan/yellow soft tissue fragment measuring 4.2 x 2.6 x 1.2 cm in greatest dimension. The soft tissue is dissected revealing 12 potential lymph nodes ranging from 0.1 to 1.2 cm in greatest dimension. The nodes are entirely submitted.

Summary of Sections

AFS1 - right superior margin.

BFS1 - right anterior margin.

CFS1 - right inferior margin.

DFS1 - right posterior margin.

EFS1 - right deep margin.

F1 - tumor to superior and medial margin.

F2 - tumor to medial and inferior margin.

F3 - tumor to anterior margin.

F4 - tumor to posterior and medial margin.

F5 - tumor to inferior and medial margin.

F6 - tumor and surface ulcer.

F7-F8 - additional tumor.

GFS1 - re-resection posterior margin.

HFS1 - re-resection inferior margin.

IFS1- re-resection inferior margin #2.

[page 9 of 9]
I2 - remainder, re-resection inferior margin #2

J1 - representative salivary gland.

J2 - four potential lymph nodes, intact.

K1 - four potential lymph nodes, intact.

K2 - three potential lymph nodes, intact.

L - six potential lymph nodes, intact.

M1 - six potential lymph nodes, intact.

M2 - six potential lymph nodes, intact.

MICROSCOPIC:

Microscopic examination is performed.

COMMENT:

The physical top slide submitted to the BCR was cut from mirrored fixed tissue, not from the actual tissue submitted to the BCR.

Criteria:	W 4/9/13	Yes	No
IIHAA Discrepancy			✓

Source: NCI Genomic Data Commons file 511fe45c-3f77-44b1-9a93-1a85ccd9b6f2 (TCGA-MT-A67A.3D36CA49-97FC-42D0-971B-63CE064A5B15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).